Somatic mutation profile of tumor specimen MP2PRT-PAPFPU-TBP1-A (aliquot MP2PRT-PAPFPU-TBP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFPU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,067 days).
Specimen MP2PRT-PAPFPU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b563dd3-da4e-47b1-b78e-0c3559829239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFPU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFPU-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c5a109f-5545-4dca-94e3-580583b8198e

The open-access MAF lists 78 somatic variants for this specimen: 61 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Nonsense Mutation 5, 5'Flank 1, Intron 1, 3'Flank 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 160/356 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs375158360; called by muse, mutect2
- ANK3 | c.8087C>T p.S2696L | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs776042210; called by muse, mutect2, varscan2
- AOX1 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 146/359 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65982257; called by muse, mutect2, varscan2
- ARHGAP28 | c.547C>T p.R183C (on ENST00000383472 / NM_001366230.1; = p.R24C on NM_001010000.3) | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs201939659, COSV51646203; called by muse, mutect2, varscan2
- CNTNAP2 | c.1062G>C p.K354N | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV100666321; called by muse, mutect2
- CTCF | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 155/285 reads (54%) | catalogued as COSV50461476; called by muse, mutect2, varscan2
- DIXDC1 | c.1252C>T p.R418W (on ENST00000440460 / NM_001037954.4; = p.R207W on NM_033425.4) | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs782508827, COSV100180179; called by muse, mutect2, varscan2
- ELF5 | c.346G>A p.E116K (on ENST00000312319 / NM_198381.2; = p.E106K on NM_001422.4) | Missense Mutation (SNP) | VAF 137/318 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.898); catalogued as rs367861770; called by muse, varscan2
- FRY | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 118/293 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1454883884, COSV66572581; called by muse, mutect2, varscan2
- HAL | c.1871G>A p.R624K | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54118542; called by muse, mutect2, varscan2
- MUC12 | c.14905C>G p.H4969D (on ENST00000379442; = p.H4826D on NM_001164462.1) | Missense Mutation (SNP) | VAF 14/425 reads (3%) | SIFT deleterious (0.01); catalogued as rs1315815756; called by muse, mutect2
- MUC2 | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs762018613; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 157/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDCD2 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1293945573; called by muse, mutect2, varscan2
- PIK3R4 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs765466339; called by muse, mutect2, varscan2
- RBM24 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 183/429 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as rs781449428; called by muse, mutect2, varscan2
- SETD5 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs765891569, COSV56711478; called by muse, mutect2, varscan2
- SLC43A1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769410310; called by muse, mutect2, varscan2
- TBCCD1 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100111968; called by muse, mutect2, varscan2
- UBA2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.344); catalogued as rs1176664885; called by muse, mutect2, varscan2
- YKT6 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 123/250 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs780133803, COSV56272711; called by muse, mutect2, varscan2
- ZNF765 | c.474G>C p.E158D | Missense Mutation (SNP) | VAF 92/247 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV67183249; called by muse, mutect2, varscan2
- AC008397.2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 124/264 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ACACA | c.5914C>T p.R1972* | Nonsense Mutation (SNP) | VAF 76/190 reads (40%) | called by muse, mutect2, varscan2
- ATP4A | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP4A | c.2124G>C p.Q708H | Missense Mutation (SNP) | VAF 153/363 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.1429A>G p.K477E | Missense Mutation (SNP) | VAF 174/375 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- C12orf56 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 200/493 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CLC | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPVL | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 84/185 reads (45%) | called by muse, mutect2, varscan2
- CRNKL1 | c.2383G>C p.D795H | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CRYL1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 58/147 reads (39%) | called by muse, mutect2, varscan2
- CYFIP2 | c.3118C>G p.Q1040E (on ENST00000616178 / NM_001291722.2; = p.Q1015E on NM_014376.4) | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DOP1A | c.1210C>G p.Q404E | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- EPHA6 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 59/334 reads (18%) | called by muse, mutect2, varscan2
- EPN3 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- GGA2 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8M | c.99C>G p.N33K | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOMEZ | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRN3 | c.119G>T p.W40L | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEDD1 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 159/343 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOVA1 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 141/318 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PIP5K1B | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RMDN2 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- RPN1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 181/376 reads (48%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- RXRB | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 119/302 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RXRB | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by mutect2, varscan2
- SNRNP200 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 122/307 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPTBN4 | c.2334C>G p.F778L | Missense Mutation (SNP) | VAF 281/580 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THBS4 | c.2723C>T p.S908F | Missense Mutation (SNP) | VAF 165/393 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRAV8-6 | c.339del p.S113Rfs*? | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | called by pindel*, varscan2
- TWF1 | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- UBA2 | c.1098C>A p.F366L | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP15 | c.408G>C p.L136F | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- USP42 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- VPS13C | c.4217C>T p.S1406L (on ENST00000644861 / NM_020821.3; = p.S1363L on NM_017684.5) | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED5 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ZNF285 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ZNF442 | c.210G>C p.M70I | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ZNF506 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZNF510 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DOP1B | c.3063G>T p.S1021= | Silent (SNP) | VAF 130/231 reads (56%) | called by muse, mutect2, varscan2
- HERC6 | c.2817C>T p.T939= | Silent (SNP) | VAF 93/233 reads (40%) | called by muse, mutect2, varscan2
- KIF4B | c.2313A>G p.R771= | Silent (SNP) | VAF 127/293 reads (43%) | called by muse, mutect2, varscan2
- NAA15 | c.1986A>G p.T662= | Silent (SNP) | VAF 73/187 reads (39%) | called by muse, mutect2, varscan2
- OR13A1 | c.690G>A p.L230= | Silent (SNP) | VAF 220/469 reads (47%) | called by muse, mutect2, varscan2
- PTGIR | c.216C>T p.F72= | Silent (SNP) | VAF 74/497 reads (15%) | catalogued as rs199583724; called by muse, mutect2, varscan2
- SERINC2 | c.90C>T p.P30= (on ENST00000373709 / NM_178865.5; = p.P34= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 140/328 reads (43%) | catalogued as rs560703832, COSV65490990; called by muse, mutect2, varscan2
- SYNM | c.762G>A p.A254= | Silent (SNP) | VAF 230/520 reads (44%) | called by muse, mutect2
- TMX3 | c.489G>A p.L163= | Silent (SNP) | VAF 69/220 reads (31%) | called by muse, mutect2, varscan2
- TPR | c.4437C>T p.L1479= | Silent (SNP) | VAF 126/323 reads (39%) | called by muse, mutect2, varscan2
- TRIM36 | c.1689C>T p.I563= | Silent (SNP) | VAF 136/329 reads (41%) | called by muse, mutect2, varscan2
- TRPM5 | c.2514C>T p.L838= | Silent (SNP) | VAF 132/310 reads (43%) | catalogued as rs148479286; called by muse, mutect2
- TUBGCP2 | c.300G>A p.Q100= | Silent (SNP) | VAF 98/204 reads (48%) | catalogued as COSV53307853; called by muse, mutect2, varscan2
- VEGFC | c.18C>T p.F6= | Silent (SNP) | VAF 142/356 reads (40%) | called by muse, varscan2
- CPLANE1 | chr5:37165617 C>G | 3'Flank (SNP) | VAF 110/278 reads (40%) | called by muse, mutect2, varscan2
- RRM2 | chr2:10122727 G>A | 5'Flank (SNP) | VAF 213/474 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.10303+2247C>T | Intron (SNP) | VAF 81/216 reads (38%) | called by muse, mutect2, varscan2
